Somatic mutation profile of tumor specimen RC-B56F-TTP1-A (aliquot RC-B56F-TTP1-A-1-1-D-A93N-47) from RC case RC-B56F, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 61.4 years (22,421 days).
Specimen RC-B56F-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5696df4e-0c87-4b6c-a78f-574a6f571e78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B56F-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B56F-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afa4f300-ea0a-4028-911e-78262821f0db

The open-access MAF lists 305 somatic variants for this specimen: 206 protein-altering or splice-affecting, 86 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 86, Nonsense Mutation 15, Intron 6, Frame Shift Del 5, RNA 3, Frame Shift Ins 2, 5'Flank 2, In Frame Del 2, Translation Start Site 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP17A1 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs61754278, CM960476, COSV64004824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.700_702del p.Y234del | In Frame Del (DEL) | VAF 25/60 reads (42%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCB4 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55935817; called by muse, mutect2, varscan2
- ABCB5 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs767761999; called by muse, mutect2, varscan2
- ACTN1 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs913554480, COSV51991205; called by muse, mutect2, varscan2
- ADAMTS10 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs782300766, COSV54351658; called by muse, mutect2, varscan2
- ADGRA1 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV63416755; called by muse, mutect2, varscan2
- ADGRB2 | c.4661C>T p.S1554L (on ENST00000373658 / NM_001364857.2; = p.S1553L on NM_001294335.2) | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1424619746, COSV57077386; called by muse, mutect2, varscan2
- ADGRG3 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 23/184 reads (13%) | catalogued as rs1354312025, COSV59650300; called by muse, mutect2, varscan2
- AKAP9 | c.8731C>T p.P2911S (on ENST00000359028; = p.P2887S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV62350925; called by muse, mutect2, varscan2
- ANK3 | c.3362G>A p.R1121H (on ENST00000280772 / NM_001320874.2; = p.R255H on NM_001149.3) | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750774209; called by muse, mutect2, varscan2
- AOX1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV65983782; called by muse, mutect2, varscan2
- AQR | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV50032210; called by muse, mutect2, varscan2
- CARD11 | c.1071C>A p.D357E | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as COSV67799473; called by muse, mutect2, varscan2
- CAVIN2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs897788525; called by muse, mutect2
- CCSER1 | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 19/111 reads (17%) | catalogued as COSV100388731; called by muse, mutect2, varscan2
- CELSR3 | c.9854C>T p.P3285L | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as COSV99373835; called by muse, mutect2, varscan2
- CHD5 | c.3590C>T p.T1197M | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52428683; called by muse, mutect2, varscan2
- CHRNA4 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs769233762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST6 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs779247810, COSV60001805; called by muse, mutect2, varscan2
- CKMT1B | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs530044813, COSV100294690; called by muse, mutect2, varscan2
- CNBD1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1190645586, COSV73074002; called by muse, mutect2
- CNTNAP4 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs1479349316, COSV56686972, COSV56693705; called by muse, mutect2, varscan2
- CNTNAP5 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs767854611, COSV70520253; called by muse, mutect2, varscan2
- COL11A1 | c.5120G>A p.R1707Q | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs751989395, COSV62175742; called by muse, mutect2, varscan2
- CUX2 | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as rs866261779, COSV55639655; called by muse, mutect2, varscan2
- CXorf21 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV66762472, COSV66763043; called by muse, mutect2, varscan2
- DCC | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs752208238, COSV100498662; called by muse, mutect2, varscan2
- DDX23 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as rs774474991; called by muse, mutect2, varscan2
- DEFB133 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs1441897576; called by muse, mutect2, varscan2
- DLGAP2 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.997); catalogued as rs144873657; called by muse, mutect2, varscan2
- DNAAF1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57578779; called by muse, mutect2, varscan2
- DNER | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs200069865; called by muse, mutect2, varscan2
- DNMBP | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as rs755674215, COSV60625548; called by muse, mutect2, varscan2
- DPY19L3 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs776706155, COSV60476626; called by muse, mutect2, varscan2
- DSEL | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.132); catalogued as rs747825242, COSV59489441; called by muse, mutect2
- DSG3 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs370583301; called by muse, varscan2
- EPHA10 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57621346; called by muse, mutect2, varscan2
- EPHA3 | c.2936G>A p.G979D | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.356); catalogued as COSV60713081; called by muse, mutect2, varscan2
- FAAH | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs765213424; called by muse, mutect2, varscan2
- FAM135B | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs187739434, COSV52708604; called by muse, mutect2, varscan2
- FBLN1 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 22/146 reads (15%) | catalogued as rs771724672, COSV53055252; called by muse, mutect2, varscan2
- FBN1 | c.8026C>A p.P2676T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.583); catalogued as CM157683; called by muse, mutect2, varscan2
- FBXO24 | c.359G>A p.R120H (on ENST00000241071 / NM_033506.3; = p.R158H on NM_012172.5) | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as rs769582338; called by muse, mutect2
- FER1L5 | c.4472C>T p.P1491L (on ENST00000623019; = p.P1464L on NM_001293083.2) | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1473586012; called by muse, mutect2, varscan2
- FHL2 | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59080034; called by muse, mutect2, varscan2
- FMN2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.006); catalogued as rs748393494, COSV60431235; called by muse, mutect2, varscan2
- FMN2 | c.3178G>A p.G1060R | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs559871488, COSV100146512; called by muse, varscan2
- GATA3 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV60518865; called by muse, mutect2, varscan2
- GJA3 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1347376632; called by muse, mutect2, varscan2
- GLDN | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs759719608; called by muse, mutect2, varscan2
- GLI3 | c.3139C>T p.Q1047* | Nonsense Mutation (SNP) | VAF 22/338 reads (7%) | catalogued as COSV101229768, COSV101229994; called by muse, mutect2
- GLRB | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.044); catalogued as COSV52417119; called by muse, mutect2, varscan2
- GPRC5B | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV56025189; called by muse, mutect2, varscan2
- GRIK2 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs771884562, COSV59759187; called by muse, mutect2, varscan2
- HECW2 | c.2501C>T p.T834M | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778764644, COSV99647693; called by muse, mutect2, varscan2
- HFM1 | c.4172C>T p.S1391F | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs754896938; called by muse, mutect2, varscan2
- KCNB1 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1338339252, COSV65568401; called by muse, mutect2, varscan2
- KCND3 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1349469134, COSV56174228, COSV56187861; called by muse, mutect2
- KIF27 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141363838; called by muse, mutect2, varscan2
- KIRREL1 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs143303568; called by muse, mutect2, varscan2
- LRP1B | c.10480C>T p.R3494W | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs751868449, COSV67190947, COSV67194761; called by muse, mutect2, varscan2
- LRRIQ3 | c.1134dup p.P379Sfs*17 | Frame Shift Ins (INS) | VAF 28/108 reads (26%) | catalogued as rs751977298; called by mutect2, varscan2
- LZTS3 | c.1709C>T p.T570M (on ENST00000329152; = p.T524M on NM_001282533.2) | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.837); catalogued as rs1404752625; called by muse, mutect2, varscan2
- MAGI2 | c.1812G>A p.M604I | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs753447813; called by muse, mutect2
- MAP3K21 | c.2858G>A p.R953H | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs138700859; called by muse, mutect2, varscan2
- MDGA2 | c.1990G>A p.E664K (on ENST00000399232 / NM_001113498.2; = p.E366K on NM_182830.4) | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100638898, COSV62121438; called by muse, mutect2, varscan2
- MELTF | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs746860496, COSV56379501; called by muse, mutect2
- MPND | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs769946757; called by muse, mutect2, varscan2
- MTSS1 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1214836042; called by muse, mutect2, varscan2
- MUC16 | c.30596C>T p.S10199F | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV67462730; called by muse, mutect2, varscan2
- MUC5AC | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.96); catalogued as rs1424584041; called by muse, mutect2, varscan2
- MUC5B | c.3674G>A p.G1225E | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs751102337; called by muse, mutect2
- MYH4 | c.3910C>T p.Q1304* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as COSV55121899; called by muse, mutect2, varscan2
- NPAP1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.282); catalogued as rs773600317, COSV61504502; called by muse, mutect2
- NR2F2 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67684312; called by muse, mutect2, varscan2
- NRXN3 | c.2444C>T p.T815M (on ENST00000335750 / NM_001330195.2; = p.T442M on NM_004796.6) | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772692723, COSV59773156; called by muse, mutect2, varscan2
- NSD1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); catalogued as rs140095431; called by muse, mutect2, varscan2
- OR56A5 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as rs1456906184; called by muse, mutect2, varscan2
- OTOF | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 117/264 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs751650771, COSV55498169; called by muse, mutect2, varscan2
- OXR1 | c.535G>T p.D179Y (on ENST00000442977 / NM_001198532.1; = p.D178Y on NM_018002.3) | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1163434426, COSV56334658; called by muse, mutect2, varscan2
- PCDHA2 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 66/536 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as COSV65367194; called by muse, mutect2, varscan2
- PCSK2 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs372392030; called by muse, mutect2, varscan2
- PHACTR3 | c.1565C>T p.T522M | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368695747, COSV63030573; called by muse, mutect2, varscan2
- PHF10 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as rs1363293671; called by muse, mutect2, varscan2
- PRICKLE1 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.947); catalogued as COSV58208230; called by muse, mutect2, varscan2
- PRICKLE2 | c.1258C>T p.R420W (on ENST00000295902; = p.R364W on NM_198859.4) | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs755313340; called by muse, mutect2, varscan2
- PRKD1 | c.524T>C p.L175P | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59574121; called by muse, mutect2, varscan2
- PROX1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1374775160, COSV99800417; called by muse, mutect2, varscan2
- PSG2 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754469616, COSV61545530; called by muse, mutect2, varscan2
- PTCHD4 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.063); catalogued as rs764551252; called by muse, mutect2, varscan2
- PTPN14 | c.3388G>A p.V1130M | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779395805; called by muse, mutect2, varscan2
- PTPN14 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.207); catalogued as rs868014027; called by muse, mutect2, varscan2
- SDK1 | c.4184G>A p.R1395Q | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs141481774; called by muse, mutect2, varscan2
- SEMA6D | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.087); catalogued as rs547323317, COSV60376540, COSV60385561; called by muse, mutect2, varscan2
- SFMBT2 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100739637; called by muse, mutect2, varscan2
- SHANK2 | c.4702G>A p.V1568M | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs1036290504, COSV99572040; called by muse, mutect2, varscan2
- SLC13A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs867764394, COSV52009873, COSV52015253; called by muse, mutect2
- SLC45A1 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 29/198 reads (15%) | catalogued as rs762670620, COSV57094164; called by muse, mutect2, varscan2
- SLC4A3 | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1213795894, COSV99812452; called by muse, mutect2, varscan2
- SLC5A12 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756737576; called by muse, mutect2, varscan2
- SLC6A14 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as rs782204139, COSV64147155; called by muse, mutect2, varscan2
- SLIT2 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1332485424; called by muse, mutect2, varscan2
- SLIT2 | c.4481C>T p.P1494L | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs568739936, COSV56600015; called by muse, mutect2, varscan2
- SLITRK1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV65675639; called by muse, mutect2, varscan2
- SMG1 | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV67170829; called by muse, mutect2, varscan2
- SPATA31A3 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1182172633; called by mutect2, varscan2
- SPG11 | c.6386C>T p.T2129M | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs375608115; called by muse, mutect2, varscan2
- SPRY4 | c.808C>T p.R270C (on ENST00000434127 / NM_001127496.3; = p.R293C on NM_030964.4) | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1396279357, COSV100702226; called by muse, mutect2, varscan2
- SULF2 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs760729379, COSV63413560; called by muse, mutect2, varscan2
- SVEP1 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100238483; called by muse, mutect2, varscan2
- SYT7 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1274898225; called by muse, mutect2, varscan2
- TBC1D8 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs374615412; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 36/212 reads (17%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, varscan2
- TDP2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745911675, COSV61967084; called by muse, mutect2, varscan2
- TEKT4 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 48/350 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as rs193072346, COSV54625491; called by muse, mutect2, varscan2
- TJP1 | c.4831C>T p.P1611S | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as rs1239208416; called by muse, mutect2, varscan2
- TLR9 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.266); catalogued as rs201482702; called by muse, mutect2, varscan2
- TNNT3 | c.722C>T p.T241M (on ENST00000397301 / NM_001367846.1; = p.T230M on NM_006757.4) | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs540840670; called by muse, mutect2, varscan2
- TSHZ3 | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as rs1220435068, COSV99553333; called by muse, mutect2, varscan2
- TTLL8 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs772658209; called by muse, mutect2, varscan2
- UBR2 | c.3874C>T p.R1292C | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as rs376653677; called by muse, mutect2, varscan2
- UMODL1 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs371828842; called by muse, mutect2, varscan2
- USP44 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1218851298; called by muse, mutect2, varscan2
- VWC2 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.053); catalogued as COSV100514861, COSV61486085; called by muse, mutect2, varscan2
- XPO1 | c.1643T>C p.V548A | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68946632; called by muse, mutect2, varscan2
- ZNF254 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 16/316 reads (5%) | catalogued as COSV61641678, COSV61642642; called by muse, mutect2
- ZNF462 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 28/193 reads (15%) | catalogued as COSV52937235; called by muse, mutect2, varscan2
- ZSCAN23 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as rs759246782, COSV99078865; called by muse, mutect2, varscan2
- ABCC11 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC008687.4 | c.850dup p.L284Pfs*86 | Frame Shift Ins (INS) | VAF 33/284 reads (12%) | called by mutect2, pindel, varscan2
- ADAD2 | c.754C>A p.H252N (on ENST00000315906 / NM_001145400.2; = p.H334N on NM_139174.4) | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AFF3 | c.2696C>T p.S899F | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- AGRN | c.5375C>T p.S1792F | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AP2B1 | c.1262A>G p.Y421C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- APOB | c.9566C>T p.P3189L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARFGEF3 | c.4516C>T p.P1506S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP29 | c.3614C>T p.S1205L | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ASXL3 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBLN4 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CD300LB | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDS1 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CFAP65 | c.1896del p.M633* | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- CHL1 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- CLEC18B | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CLIP3 | c.1198_1199del p.P400Ifs*12 | Frame Shift Del (DEL) | VAF 23/184 reads (13%) | called by mutect2, pindel, varscan2
- COL3A1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); called by mutect2, varscan2
- CYP4F3 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DHX8 | c.3165_3167del p.N1055del | In Frame Del (DEL) | VAF 20/122 reads (16%) | called by pindel, varscan2
- DSC3 | c.499T>A p.Y167N | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- EFCAB5 | c.3424C>T p.Q1142* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- EN1 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.253); called by muse, mutect2
- FRG2C | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2
- FRMD5 | c.458A>G p.H153R | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRYL | c.6818C>T p.P2273L | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- FSBP | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FSIP1 | c.1327C>A p.Q443K | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2
- GALNT17 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); called by muse, mutect2
- GOLGA6D | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- GPRC5C | c.470A>G p.D157G (on ENST00000652232; = p.D112G on NM_018653.4) | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- HHATL | c.1348C>T p.L450F | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- HNF4G | c.1024C>T p.P342S (on ENST00000354370 / NM_001330561.2; = p.P389S on NM_004133.5) | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- HS3ST3A1 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by mutect2, varscan2
- HSD17B3 | c.593A>T p.Y198F | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- KANK2 | c.1758_1760+24del p.X586_splice (on ENST00000586659 / NM_001379562.1; = p.X594_splice on NM_015493.7 and 7 other RefSeq transcripts) | Splice Site (DEL) | VAF 38/101 reads (38%) | called by pindel, varscan2*
- KCTD3 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- KHDC4 | c.699T>A p.D233E | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LNPEP | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LNX1 | c.1381T>C p.S461P (on ENST00000263925 / NM_001126328.3; = p.S365P on NM_032622.2) | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP3K4 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCM4 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPHOSPH8 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH7 | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- MYO15B | c.3796C>A p.Q1266K | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.182); called by muse, varscan2
- NEU3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR56A5 | c.298T>G p.C100G | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OSBPL10 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PDE3B | c.2376C>A p.C792* | Nonsense Mutation (SNP) | VAF 14/175 reads (8%) | called by muse, mutect2
- PHLPP2 | c.1673A>T p.N558I | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLEC | c.10427A>G p.K3476R (on ENST00000322810 / NM_201380.4; = p.K3366R on NM_000445.5) | Missense Mutation (SNP) | VAF 121/280 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PPFIA4 | c.2983C>T p.R995* (on ENST00000447715; = p.R996* on NM_001304331.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- PWWP3B | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBBP8 | c.1390T>C p.S464P | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RHOT2 | c.1653_1665del p.P553Lfs*59 | Frame Shift Del (DEL) | VAF 70/243 reads (29%) | called by mutect2, pindel, varscan2
- RIPK4 | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SEMA5B | c.2741C>T p.S914F | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC25A3 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC26A8 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SLIT2 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMTN | c.2472C>G p.F824L | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SP2 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SVIL | c.4090C>T p.P1364S (on ENST00000355867 / NM_021738.3; = p.P938S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TANK | c.607_610del p.N203Efs*93 | Frame Shift Del (DEL) | VAF 48/95 reads (51%) | called by mutect2, pindel, varscan2
- TLR3 | c.668T>A p.L223* | Nonsense Mutation (SNP) | VAF 49/149 reads (33%) | called by muse, mutect2, varscan2
- TRBJ2-4 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 29/267 reads (11%) | called by muse, mutect2, varscan2
- TRPC5 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC34 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- UGGT2 | c.112C>A p.H38N | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP25 | c.125A>T p.D42V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- VAC14 | c.566A>G p.Q189R | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- VPS35L | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF117 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZNF439 | c.1038A>C p.R346S | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ZNF804A | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF84 | c.1175G>C p.R392T | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- AATK | c.1740C>T p.H580= (on ENST00000326724 / NM_001080395.3; = p.H477= on NM_004920.2) | Silent (SNP) | VAF 55/289 reads (19%) | catalogued as rs763163937; called by muse, mutect2, varscan2
- ABCC11 | c.1953C>T p.D651= | Silent (SNP) | VAF 29/278 reads (10%) | catalogued as rs139564847; called by muse, mutect2, varscan2
- ADAMTS5 | c.2631G>A p.P877= | Silent (SNP) | VAF 53/132 reads (40%) | catalogued as rs764765778, COSV53175794; called by muse, mutect2, varscan2
- ARSG | c.1122C>T p.A374= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs201031767; called by muse, mutect2, varscan2
- ATRN | c.627G>A p.E209= | Silent (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- BPIFA1 | c.220C>T p.L74= | Silent (SNP) | VAF 52/172 reads (30%) | called by muse, mutect2, varscan2
- BPIFB2 | c.168C>T p.F56= | Silent (SNP) | VAF 29/172 reads (17%) | catalogued as COSV50067253; called by muse, mutect2, varscan2
- C19orf84 | c.54G>A p.P18= | Silent (SNP) | VAF 60/189 reads (32%) | catalogued as rs967309558; called by muse, mutect2, varscan2
- CACNA1B | c.6864G>A p.S2288= | Silent (SNP) | VAF 58/222 reads (26%) | catalogued as rs1368182717; called by muse, mutect2, varscan2
- CACNA2D3 | c.3000C>T p.I1000= | Silent (SNP) | VAF 31/120 reads (26%) | called by muse, mutect2, varscan2
- CELF5 | c.576C>T p.H192= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as rs1314852096; called by muse, mutect2, varscan2
- CELSR3 | c.9855C>T p.P3285= | Silent (SNP) | VAF 26/209 reads (12%) | called by muse, mutect2, varscan2
- CFAP77 | c.408C>T p.I136= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as rs201835993, COSV58013038; called by muse, mutect2, varscan2
- CHGB | c.1842G>A p.R614= | Silent (SNP) | VAF 49/179 reads (27%) | catalogued as rs868322514, COSV66761540; called by muse, mutect2, varscan2
- CLMN | c.1236G>A p.K412= | Silent (SNP) | VAF 37/203 reads (18%) | called by muse, mutect2, varscan2
- CSMD1 | c.8691G>A p.T2897= (on ENST00000520002; = p.T2896= on NM_033225.6) | Silent (SNP) | VAF 28/218 reads (13%) | catalogued as rs1390743618, COSV59276636, COSV59330022; called by muse, mutect2, varscan2
- CSPG4 | c.3324C>T p.S1108= | Silent (SNP) | VAF 34/197 reads (17%) | catalogued as rs777826922, COSV100414000; called by muse, mutect2, varscan2
- CUX2 | c.4278C>T p.G1426= | Silent (SNP) | VAF 29/204 reads (14%) | catalogued as rs551398013; called by muse, mutect2, varscan2
- DCSTAMP | c.90C>T p.I30= | Silent (SNP) | VAF 81/191 reads (42%) | called by muse, mutect2, varscan2
- DNAH17 | c.1941C>T p.G647= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as rs754837443; called by muse, mutect2, varscan2
- DNAH8 | c.1701C>T p.V567= | Silent (SNP) | VAF 19/165 reads (12%) | called by muse, mutect2
- DRD1 | c.1062G>A p.T354= | Silent (SNP) | VAF 21/155 reads (14%) | catalogued as rs756872143, COSV67104569; called by muse, mutect2, varscan2
- EPPK1 | c.5964G>A p.P1988= | Silent (SNP) | VAF 40/288 reads (14%) | catalogued as rs371636220; called by muse, mutect2, varscan2
- FBN1 | c.228C>T p.G76= | Silent (SNP) | VAF 19/154 reads (12%) | catalogued as rs141651917, COSV57309315; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXW11 | c.540A>C p.G180= | Silent (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- FLT1 | c.1848C>T p.S616= | Silent (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- FMN2 | c.474G>A p.P158= | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as rs1198977248, COSV60417397; called by muse, varscan2
- FRAS1 | c.11382C>T p.F3794= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as COSV53608983; called by muse, mutect2, varscan2
- GABRB3 | c.1215G>A p.Q405= | Silent (SNP) | VAF 38/212 reads (18%) | called by muse, mutect2, varscan2
- GALNT17 | c.1593C>T p.S531= | Silent (SNP) | VAF 18/256 reads (7%) | catalogued as rs1282527210; called by muse, mutect2
- GATA5 | c.279C>T p.F93= | Silent (SNP) | VAF 32/251 reads (13%) | called by muse, mutect2, varscan2
- GCM1 | c.396G>A p.P132= | Silent (SNP) | VAF 22/161 reads (14%) | catalogued as rs368156130; called by muse, mutect2, varscan2
- GFM1 | c.825G>A p.S275= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV51832714; called by muse, mutect2, varscan2
- GRIK2 | c.519G>A p.T173= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as rs147153195; called by muse, mutect2, varscan2
- HHIPL2 | c.336C>T p.Y112= | Silent (SNP) | VAF 29/193 reads (15%) | catalogued as rs376894621; called by muse, mutect2, varscan2
- HNF4G | c.306C>T p.P102= (on ENST00000354370 / NM_001330561.2; = p.P149= on NM_004133.5) | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs1432625609, COSV62974262; called by muse, mutect2, varscan2
- HOXA9 | c.222C>T p.G74= | Silent (SNP) | VAF 48/395 reads (12%) | called by muse, mutect2, varscan2
- KCTD3 | c.1338G>A p.T446= | Silent (SNP) | VAF 20/194 reads (10%) | catalogued as rs1011849079, COSV52067106; called by muse, mutect2
- KRTAP13-1 | c.438C>T p.F146= | Silent (SNP) | VAF 38/229 reads (17%) | catalogued as COSV100819891; called by muse, mutect2, varscan2
- LRP3 | c.2013C>T p.P671= | Silent (SNP) | VAF 43/260 reads (17%) | catalogued as rs576868212; called by muse, mutect2, varscan2
- LYZL2 | c.303C>T p.S101= (on ENST00000375318; = p.S55= on NM_183058.3) | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as rs757127551, COSV64684295; called by muse, mutect2
- MAP2K2 | c.109C>T p.L37= | Silent (SNP) | VAF 19/147 reads (13%) | called by muse, mutect2, varscan2
- MAP3K4 | c.27C>T p.V9= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as rs750190300; called by muse, mutect2, varscan2
- MCF2L | c.1686G>A p.T562= (on ENST00000375608; = p.T530= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/226 reads (8%) | catalogued as rs377733844; called by muse, mutect2
- MFSD2A | c.1017C>T p.R339= (on ENST00000372809 / NM_001136493.3; = p.R326= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- MLXIPL | c.435C>T p.F145= | Silent (SNP) | VAF 36/323 reads (11%) | catalogued as rs1554598751, COSV57667523; called by muse, mutect2, varscan2
- MMRN2 | c.1569C>T p.D523= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as rs141447174, COSV64400349; called by muse, mutect2, varscan2
- MTUS2 | c.255G>A p.G85= | Silent (SNP) | VAF 30/172 reads (17%) | called by muse, mutect2, varscan2
- NOBOX | c.546G>A p.G182= | Silent (SNP) | VAF 45/420 reads (11%) | catalogued as rs1184207268; called by muse, mutect2, varscan2
- NPHP1 | c.1128G>A p.S376= (on ENST00000393272 / NM_207181.4; = p.S377= on NM_000272.5) | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as rs533125951, COSV100337819; ClinVar: likely benign; called by muse, mutect2, varscan2
- NTN4 | c.1638G>A p.V546= | Silent (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- NUMA1 | c.117C>T p.I39= | Silent (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2, varscan2
- NYNRIN | c.3291C>T p.F1097= | Silent (SNP) | VAF 20/191 reads (10%) | catalogued as rs1319221221; called by muse, mutect2
- OBSCN | c.13149G>A p.S4383= | Silent (SNP) | VAF 58/288 reads (20%) | catalogued as rs745756499; called by muse, mutect2, varscan2
- PIK3CA | c.2397C>T p.I799= | Silent (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- PLVAP | c.1269G>A p.R423= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs746069692; called by muse, mutect2, varscan2
- PNMA2 | c.561G>A p.Q187= | Silent (SNP) | VAF 29/311 reads (9%) | called by muse, mutect2
- PNMA8A | c.861G>A p.P287= | Silent (SNP) | VAF 70/213 reads (33%) | catalogued as rs377335947; called by muse, mutect2, varscan2
- PSD | c.81C>T p.P27= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs534236516; called by muse, mutect2, varscan2
- PTPRF | c.3204G>A p.Q1068= | Silent (SNP) | VAF 37/194 reads (19%) | called by muse, mutect2, varscan2
- RBMXL2 | c.645G>A p.S215= | Silent (SNP) | VAF 52/181 reads (29%) | catalogued as COSV60981811; called by muse, mutect2, varscan2
- RNASE7 | c.279C>T p.G93= | Silent (SNP) | VAF 41/192 reads (21%) | catalogued as rs765714743, COSV53876773; called by muse, mutect2, varscan2
- RPTOR | c.3789C>T p.P1263= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV100156980; called by muse, mutect2, varscan2
- RYR1 | c.3267C>T p.F1089= | Silent (SNP) | VAF 59/195 reads (30%) | catalogued as rs1302567016, COSV100615171, COSV62089673; called by muse, mutect2, varscan2
- SCRT1 | c.699C>T p.S233= | Silent (SNP) | VAF 48/305 reads (16%) | called by muse, mutect2, varscan2
- SEMA6B | c.1767C>T p.D589= | Silent (SNP) | VAF 30/184 reads (16%) | called by muse, mutect2, varscan2
- SERGEF | c.750C>T p.F250= | Silent (SNP) | VAF 27/183 reads (15%) | catalogued as COSV56383042; called by muse, mutect2, varscan2
- SERINC2 | c.219G>A p.E73= (on ENST00000373709 / NM_178865.5; = p.E77= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- SLC13A4 | c.519C>T p.T173= | Silent (SNP) | VAF 31/208 reads (15%) | catalogued as rs762571314; called by muse, mutect2, varscan2
- SLC1A1 | c.771T>C p.Y257= | Silent (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- SLC22A11 | c.384C>T p.I128= | Silent (SNP) | VAF 31/189 reads (16%) | catalogued as rs748728205; called by muse, varscan2
- SLC39A11 | c.711C>T p.I237= (on ENST00000542342 / NM_001159770.2; = p.I230= on NM_139177.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/151 reads (15%) | catalogued as rs186594537, COSV99722891; called by muse, mutect2, varscan2
- SLC50A1 | c.309C>T p.T103= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as rs968166217; called by muse, mutect2, varscan2
- SLC7A11 | c.1383C>T p.V461= | Silent (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- SNAP23 | c.387A>G p.Q129= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as rs760440034; called by muse, mutect2, varscan2
- SPATA20 | c.1776G>A p.Q592= (on ENST00000356488 / NM_001258372.1; = p.Q608= on NM_022827.4) | Silent (SNP) | VAF 33/220 reads (15%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.717C>T p.R239= | Silent (SNP) | VAF 69/266 reads (26%) | catalogued as rs780852002, COSV64528065; called by muse, mutect2, varscan2
- SVEP1 | c.3201G>A p.E1067= | Silent (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- SYAP1 | c.171C>T p.F57= | Silent (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- TGM7 | c.1065C>T p.N355= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as rs752669926, COSV71772539, COSV71772587; called by muse, mutect2, varscan2
- THPO | c.1173C>T p.H391= (on ENST00000649095 / NM_001290003.1; = p.H251= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 44/164 reads (27%) | catalogued as rs140658452, COSV52615328; called by muse, mutect2, varscan2
- TP73 | c.603G>A p.R201= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV60701824; called by muse, mutect2, varscan2
- TUBB8 | c.936G>A p.T312= | Silent (SNP) | VAF 34/273 reads (12%) | catalogued as rs782449939; called by muse, mutect2, varscan2
- UGT2A2 | c.420G>A p.K140= | Silent (SNP) | VAF 41/210 reads (20%) | called by muse, mutect2, varscan2
- UGT2B7 | c.1143C>T p.Y381= | Silent (SNP) | VAF 68/205 reads (33%) | catalogued as rs760768829, COSV59444289; called by muse, mutect2, varscan2
- USP9Y | c.2787C>T p.A929= | Silent (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- AP001880.2 | n.341C>T | RNA (SNP) | VAF 33/197 reads (17%) | catalogued as rs897740956; called by muse, mutect2, varscan2
- CDK10 | chr16:89682483 G>A | 5'Flank (SNP) | VAF 15/163 reads (9%) | catalogued as rs988889621; called by muse, mutect2, varscan2
- CTBP2 | c.58+11656G>A | Intron (SNP) | VAF 38/231 reads (16%) | called by muse, mutect2, varscan2
- DCHS2 | n.3304C>T | RNA (SNP) | VAF 33/191 reads (17%) | catalogued as rs1390172512, COSV59727241; called by muse, mutect2, varscan2
- IGHA1 | chr14:105704481 G>A | 3'Flank (SNP) | VAF 28/222 reads (13%) | called by muse, mutect2, varscan2
- LIN7A | c.82+446G>A | Intron (SNP) | VAF 44/221 reads (20%) | called by muse, mutect2, varscan2
- SAP25 | chr7:100573720 C>T | 5'Flank (SNP) | VAF 25/258 reads (10%) | called by muse, mutect2
- SERF2 | c.*113C>T | 3'UTR (SNP) | VAF 40/203 reads (20%) | called by muse, mutect2, varscan2
- SHTN1 | c.1359+244C>T | Intron (SNP) | VAF 45/138 reads (33%) | called by muse, mutect2, varscan2
- TUBB4BP6 | n.149G>A | RNA (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23303G>A | Intron (SNP) | VAF 39/234 reads (17%) | catalogued as rs373030535; called by muse, mutect2, varscan2
- VPS35L | c.434-38G>A | Intron (SNP) | VAF 29/157 reads (18%) | called by muse, mutect2, varscan2
- ZDHHC11B | c.1023+1108C>T | Intron (SNP) | VAF 24/121 reads (20%) | called by muse, mutect2, varscan2
